Surgical pathology report (de-identified scan), TCGA case TCGA-KC-A7FE, project TCGA-PRAD (Prostate Adenocarcinoma), tissue source site Cornell Medical College, specimen TCGA-KC-A7FE-01A (Primary Tumor).

[page 1 of 4]
Patient:
MRN:
DOB:
SEX: Male

SURGICAL PATHOLOGY, COMPREHENSIVE

Status: Final result Not Released

Surgical Pathology

Inquiry:
Fax:

Surgical Pathology Report

Specimen Date:
In Lab Date:
Report Date:

Patient:

MRN:

Encounter #:
Location:
Age/ Sex:

CLINICAL INFORMATION:
Prostate cancer.

INTRAOPERATIVE DIAGNOSIS:

A. Frozen section diagnosis: Disintegrated on processing.
Reported to:

B-F. Frozen section diagnosis: Negative. Soft tissue only.

Reported to:

GROSS DESCRIPTION:

A. Received fresh, the specimen is labeled "right anterior apical" and consists of a 0.3 x 0.3 x 0.1 cm piece of pink-tan soft tissue. Disintegrated during frozen section.

B. Received fresh, the specimen is labeled "right lateral apical" and consists of a 0.5 x 0.2 x 0.1 cm piece of pink-tan soft tissue. 100% frozen for intraoperative consultation.
Summary of sections: B1 FSC.

C. Received fresh, the specimen is labeled "right posterior apical" and consists of a 0.3 x 0.2 x 0.1 cm piece of pink-tan soft tissue. 100% frozen for intraoperative consultation.
Summary of sections: C1 FSC.

D. Received fresh, the specimen is labeled "right base posterior lateral" and consists of a 0.4 x 0.2 x 0.1 cm piece of pink-tan soft tissue. 100% frozen for intraoperative consultation.
Summary of sections: D1 FSC.

E. Received fresh, the specimen is labeled "right mid posterior lateral" and consists of a 0.2 x 0.2 x 0.1 cm piece of pink-tan

ICD-6-3
C&CF
Adenocarcinoma, acinar
Path
Adenocarcinoma NOS
8140/3
Site Prostate NOS
C61.9
QJ 9/26/13

[page 2 of 4]
soft tissue. 100% frozen for intraoperative consultation.
Summary of sections: E1 FSC.

F. Received fresh, the specimen is labeled "final right anterior" and consists of a 0.5 x 0.4 x 0.2 cm piece of pink-tan soft tissue. 100% frozen for intraoperative consultation.
Summary of sections: F1 FSC.

G. Received fresh, the specimen is labeled "prostate gland and seminal vesicles", and consists of a 65.98 gram radical prostatectomy specimen including a 5.5 x 4.5 x 3.5 cm prostate, a 4.0 x 1.5 x 0.5 cm left seminal vesicle, a 2.5 x 0.5 x 0.5 cm left vas deferens, a 3.0 x 1.5 x 0.5 cm right seminal vesicle, and a 2.0 x 0.5 x 0.5 cm right vas deferens. The right side of the specimen is inked green and the left side is inked black. The seminal vesicle base, bladder neck and apical margins are shaved and submitted. The prostate is serially sectioned from the apex to base with sections designated from A to F respectively. On sectioning, multiple nodular and cystic areas are seen. The section labeled B is submitted for research. The prostate is submitted entirely. Summary of sections: G1-RSV LSV, G2-right anterior base, G3-right posterior base, G4-left anterior base, G5-G6-left posterior base, G7-right anterior apex, G8-right posterior apex, G9-left anterior apex, G10-left posterior apex, G11-ARA (portion of ink missing on anterior of this section), G12-ARP (portion of ink missing on the section), G13-ALA (portion of ink missing on anterior of this section), G14-ALP, G15-CRA, G16-CRP, G17-CLA, G18-CLP, G19-DRA, G20-DRP, G21-DLA, G22-DLP, G23-ERA, G24-ERP (possible portion of ink missing), G25-ELA, G26-ELP, G27-FRA, G28-FRP, G29-FLA, G30-FLP.

H. Received fresh, the specimen is labeled "pelvic lymph nodes" and consists of a 4 x 3.5 x 1 cm piece of fibroadipose tissue and lymph nodes. 100% submitted. Summary of sections: H1-2 lymph nodes, H2- H6-remaining tissue.

I. Received fresh, the specimen is labeled "anterior prostatic fat" and consists of a 4 x 3.5 x 0.3 cm aggregate of fibroadipose tissue. 100% submitted. Summary of sections: I1-I2.

DIAGNOSIS:

- A. Prostate, right anterior margin (biopsy):
Disintegrated on processing.
- B. Prostate, right lateral apical margin (biopsy):
Fibromuscular tissue and nerve.
No prostatic glands or carcinoma identified.
- C. Prostate, right posterior apical margin (biopsy):
Adipose and fibromuscular tissue and nerve.
No prostatic glands or carcinoma identified.
- D. Prostate, right base posterior lateral margin (biopsy):
Fibroadipose tissue, vessels and nerve.
No prostatic glands or carcinoma seen.
- E. Prostate, right mid posterior lateral margin (biopsy):
Fibromuscular tissue and nerve.
No prostatic glands or carcinoma identified.
- F. Prostate, final right anterior margin (biopsy):
Adipose and fibromuscular tissue.

[page 3 of 4]
No prostatic glands or carcinoma identified.

G Prostate gland and seminal vesicles (radical prostatectomy):
Prostatic adenocarcinoma, Gleason score 3+4=7,
bilateral.

Carcinoma is focally present at the left anterior
apical margin.

Linear length of positive margin <1 mm
Gleason score at positive margin 3+3=6.

Seminal vesicles and other surgical margins are
negative for tumor.

Please see attached Pathological Staging Summary.

H Pelvic lymph nodes (excision):
Two lymph nodes, negative for metastatic carcinoma
(0/2).

I Anterior prostatic fat (excision):
Fibroadipose tissue.

SYNOPSIS DIAGNOSIS:

Histologic Type:	Adenocarcinoma
(conventional, not otherwise specified)	
	Primary Pattern: Grade 3
	Secondary Pattern: Grade 4
	Total Gleason Score: 7
	Proportion (percent) of
Tumor Quantitation:	
prostatic tissue involved by tumor: 10%	
Pathologic Staging (pTNM):	pT2c: Bilateral disease
	pN0: No regional lymph
node metastasis	
	Number of regional lymph
nodes examined: 2	
	Number of regional lymph
nodes involved: 0	
	pMX: Distant metastasis
cannot be assessed	
Margins:	Apical margin(s) involved
by invasive carcinoma	
Extraprostatic Extension:	Absent
Seminal Vesicle Invasion:	Absent
Perineural Invasion:	Present
Venous (Large Vessel) Invasion (V):	Absent
Lymphatic (Small Vessel) Invasion (L):	Absent
Additional Pathologic Findings:	High-grade prostatic
intraepithelial neoplasia (PIN)	

** Electronically Signed Out **

Attending Pathologist

The attending pathologist whose signature appears on this
report has reviewed the diagnostic slides, and has edited
the gross and microscopic portions of the report in rendering the
final diagnosis.

ICD9 Codes: A-1; 185

Billing Codes: A; (Inpatient)

[page 4 of 4]
B-F
B-F,
G
H

SNOMED:

Slides: A-0, B-3, C-4, D-2, E-2, F-2, G-30, H-6, I-2
Resulting Agency

Specimen Collected:

Last Resulted:

Order Information Lab Collection Information. Order Information. Order Providers

Source: NCI Genomic Data Commons file 3527cabd-1c9c-402d-9140-4d95329aea5c (TCGA-KC-A7FE.715B093C-7832-46EA-AC95-01406A90D529.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).